Gene-level copy-number profile of tumor specimen TCGA-60-2695-01A from TCGA case TCGA-60-2695, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 74.5 years (27,211 days).
Specimen TCGA-60-2695-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.4531469d-28be-48e8-bd59-33625ee5946d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-60-2695-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/82146e55-556b-4c3a-948b-30be8e9a384c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,175; copy number 2: 32,362; copy number 3: 18,866; copy number 4: 3,759; copy number 5: 1,315; copy number 6: 1,272; copy number 7: 55; copy number 8: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-60-2695-01A-01D-0844-01): tumor purity 0.81, ploidy 2.52, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,652 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–181,238,604, 1,234 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–51,275,734, 725 genes, copy number 5–6 (broad region; genes not listed).
- chr8:127,289,817–127,482,139, 1 gene, copy number 5 (within-gene range 4–5): CASC8.
- chr8:127,322,183–127,636,867, 3 genes, copy number 5 (within-gene range 4–5): POU5F1B, CCAT2, AC104370.1.
- chr22:16,897,445–17,022,570, 10 genes, copy number 8: AC006548.1, IGKV1OR22-5, IGKV2OR22-4, IGKV2OR22-3, IGKV3OR22-2, IGKV1OR22-1, AC006548.3, GAB4, AC006548.2, VN1R9P.
- chr22:20,198,729–22,245,515, 144 genes, copy number 6–7 (broad region; genes not listed).
- chr22:23,145,326–35,002,862, 386 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr22:36,172,422–39,155,945, 149 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,032. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
